Surgical pathology report (de-identified scan), TCGA case TCGA-RQ-A68N, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RQ-A68N-01A (Primary Tumor).

[page 1 of 2]
Tumor ID #

Date of Surgery:

Diffuse Large B Cell
Lymphoma 9680/3
Site: Brain Stem C71.7
Op 6/28/13

Microscopic Description:

Sections demonstrate sheets of poorly cohesive, large cells. These have large atypical, somewhat open nuclei, usually with multiple nucleoli. They have only a modest amount of cytoplasm. Numerous mitotic figures are seen. Individual apoptotic cells are seen without frank necrosis. The tumor has an expansive interface with the surrounding parenchyma but an angiocentric pattern is also appreciated. Areas of apparent glial and fibrous scarring are also noted.

Diagnosis:

Brainstem Tumor: diffuse Large Cell Lymphoma, B-cell type

Qual/Syn. Primary		

[page 2 of 2]
ANATOMIC PATHOLOGY REPORT
PERMANENT CHART COPY

NEUROPATHOLOGY REPORT

GROSS DESCRIPTION:

MICROSCOPIC DESCRIPTION:

1, 2. Sections demonstrate sheets of poorly cohesive, large cells. These have large atypical, somewhat open nuclei, usually with multiple nucleoli. They have only a modest amount of cytoplasm. Numerous mitotic figures are seen. Individual apoptotic cells are seen without frank necrosis. The tumor has an expansive interface with the surrounding parenchyma but an angiocentric pattern is also appreciated. Areas of apparent glial and fibrous scarring are also noted.

The neoplastic cells are immunoreactive for CD45 and CD20, confirming B-cell lymphocytic origin. They are negative for GFAP, S-100 and cytokeratin 8/18.

The neoplastic cells demonstrate aberrant expression of the T-cell marker CD43 but are negative for CD3 and CD45 ro. They demonstrate BCL2 and BCL6 positivity but are negative for CD10. Overall, the immunophenotype is consistent with a diffuse large cell B-cell lymphoma.

DIAGNOSIS:

(PROVISIONAL):

- 1, 2. BRAINSTEM TUMOR, BIOPSIES:
DIFFUSE LARGE CELL LYMPHOMA, B-CELL TYPE

The tumor is negative for CD3
and CD45 ro, consistent
with a B-cell lymphoma.

Source: NCI Genomic Data Commons file b94db039-e403-4788-8ac0-8da76b33fc8e (TCGA-RQ-A68N.B40907C0-DA7B-436F-993A-53DA4C9A56A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).